Somatic mutation profile of tumor specimen TCGA-EP-A26S-01A (aliquot TCGA-EP-A26S-01A-11D-A16V-10) from TCGA case TCGA-EP-A26S, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.3 years (25,677 days).
Specimen TCGA-EP-A26S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c194e2c-9167-4942-911a-316073a4e0ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EP-A26S-10A (Blood Derived Normal), aliquot TCGA-EP-A26S-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/901acbae-649a-41ba-afc7-c8a92138c5a2

The open-access MAF lists 111 somatic variants for this specimen: 74 protein-altering or splice-affecting, 29 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 29, Frame Shift Del 5, Intron 4, RNA 2, 3'UTR 2, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 48/102 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1997A>C p.K666T | Missense Mutation (SNP) | VAF 50/111 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs374250186, COSV59205833, COSV59206062, COSV59207657; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALB | c.905G>T p.C302F | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55742563; called by muse, mutect2, varscan2
- ANXA3 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV53717424; called by muse, mutect2, varscan2
- ATP8A2 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.988); catalogued as COSV67717438; called by muse, mutect2
- BTBD2 | c.445A>G p.M149V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV55310657; called by muse, mutect2
- CADM2 | c.738G>T p.L246F (on ENST00000407528 / NM_001167674.2; = p.L248F on NM_153184.4) | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67404432; called by muse, mutect2, varscan2
- CD300LF | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146550147; called by muse, mutect2, varscan2
- CEP192 | c.6947T>C p.V2316A | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58067178; called by mutect2, varscan2
- CLEC17A | c.283A>T p.S95C | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.187); catalogued as COSV60429750; called by muse, mutect2, varscan2
- COL11A2 | c.2202T>A p.H734Q (on ENST00000341947 / NM_080680.3; = p.H627Q on NM_080679.2) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.767); catalogued as COSV59502456; called by muse, mutect2, varscan2
- CPT1B | c.1362C>G p.D454E | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56419026; called by muse, mutect2, varscan2
- CUZD1 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.231); catalogued as rs866395304, COSV59028195; called by muse, mutect2, varscan2
- DCAF6 | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV56585316; called by muse, mutect2, varscan2
- DLX4 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV53591923; called by muse, mutect2, varscan2
- DNAH2 | c.12071A>G p.Y4024C | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66727258; called by muse, mutect2, varscan2
- DUOXA2 | c.273C>A p.S91R | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50994894; called by muse, mutect2, varscan2
- EP300 | c.3764A>T p.H1255L | Missense Mutation (SNP) | VAF 95/203 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54345540, COSV54345562; called by muse, mutect2, varscan2
- FAM161B | c.1418A>T p.H473L (on ENST00000651776; = p.H410L on NM_152445.3) | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.747); catalogued as COSV54104353; called by muse, mutect2, varscan2
- FBXL4 | c.1748C>A p.S583Y | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV57750056; called by muse, mutect2, varscan2
- GAS2L1 | c.375G>T p.E125D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.262); catalogued as COSV53331959; called by muse, mutect2, varscan2
- HIPK4 | c.197A>G p.D66G | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV52525671; called by muse, mutect2, varscan2
- HMCN1 | c.12866C>T p.P4289L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54941589; called by muse, mutect2, varscan2
- HNRNPUL2 | c.553A>C p.S185R | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.17); catalogued as COSV53666724; called by muse, mutect2, varscan2
- IGF1R | c.3654C>G p.N1218K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51294639, COSV51383875; called by muse, varscan2
- JAK3 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs777849274, COSV71685924; called by muse, mutect2, varscan2
- KCNA7 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546430763, COSV55502946; called by muse, mutect2, varscan2
- KRT1 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52869285; called by muse, mutect2, varscan2
- MLXIP | c.830T>C p.L277P | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59837919; called by muse, mutect2, varscan2
- MPP6 | c.927G>C p.M309I | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV56042916, COSV99757614; called by muse, mutect2, varscan2
- NOVA1 | c.985C>A p.L329I | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0.117); catalogued as COSV104387786, COSV57487704; called by muse, mutect2, varscan2
- ODF2 | c.1835A>C p.E612A (on ENST00000434106 / NM_153433.2; = p.E588A on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV63547003, COSV63547017; called by muse, mutect2, varscan2
- OR10Z1 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV63526533; called by muse, mutect2, varscan2
- OR2T27 | c.179A>T p.Y60F | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV61283647; called by muse, mutect2, varscan2
- OR6K2 | c.344C>G p.T115R | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV62744219; called by muse, mutect2, varscan2
- OR6P1 | c.96del p.F32Lfs*6 | Frame Shift Del (DEL) | VAF 7/53 reads (13%) | catalogued as rs201077183; called by mutect2, varscan2
- PLEKHA1 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV64570385; called by muse, mutect2, varscan2
- PLEKHG1 | c.4070T>G p.L1357R | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100651554, COSV62051136; called by muse, mutect2
- PPP2R5E | c.929G>A p.W310* | Nonsense Mutation (SNP) | VAF 30/79 reads (38%) | catalogued as COSV61744266; called by muse, mutect2, varscan2
- PSAP | c.11T>A p.L4H | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV67551208; called by muse, mutect2, varscan2
- PTPRQ | c.3262G>A p.V1088I (on ENST00000616559; = p.V1046I on NM_001145026.2) | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.967); catalogued as COSV57054185; called by muse, mutect2, varscan2
- PVRIG | c.720C>A p.C240* | Nonsense Mutation (SNP) | VAF 28/93 reads (30%) | catalogued as COSV52782821; called by muse, mutect2, varscan2
- RAB3IP | c.184T>G p.S62A (on ENST00000550536 / NM_175623.4; = p.S46A on NM_022456.5) | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV56086675; called by muse, mutect2, varscan2
- RPF2 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.936); catalogued as COSV64370848; called by muse, mutect2, varscan2
- RPS6KA5 | c.2252C>G p.T751S | Missense Mutation (SNP) | VAF 105/215 reads (49%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.931); catalogued as COSV56225695; called by muse, mutect2, varscan2
- RTL3 | c.728C>A p.T243N | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV58185907; called by muse, mutect2, varscan2
- SCARF2 | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171784827, COSV56733988; called by muse, mutect2, varscan2
- SERPINB13 | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs139825462; called by muse, mutect2, varscan2
- SETD1A | c.2003G>T p.R668L | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV52692464; called by muse, mutect2, varscan2
- SHCBP1L | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV62357210; called by muse, mutect2, varscan2
- SHPRH | c.1741G>T p.V581F | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.153); catalogued as rs986945792, COSV51617763; called by muse, mutect2, varscan2
- SMIM14 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 83/192 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV55904668; called by muse, mutect2, varscan2
- SPTA1 | c.5416G>C p.E1806Q | Missense Mutation (SNP) | VAF 50/64 reads (78%) | SIFT tolerated (0.64); PolyPhen benign (0.115); catalogued as COSV100935033, COSV63759387; called by muse, mutect2, varscan2
- SYT16 | c.1441G>T p.G481W | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV70859933; called by muse, mutect2, varscan2
- TBC1D17 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs758641196, COSV55581289; called by muse, mutect2, varscan2
- TENM3 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.898); catalogued as COSV101304913, COSV69319276; called by muse, mutect2, varscan2
- TMEM260 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.407); catalogued as COSV55102653; called by muse, mutect2, varscan2
- TMPO | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58463724; called by muse, mutect2, varscan2
- TMTC1 | c.2638G>A p.D880N (on ENST00000539277 / NM_001193451.2; = p.D772N on NM_175861.3) | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV55493594; called by muse, mutect2, varscan2
- TRAIP | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV58916746; called by muse, mutect2, varscan2
- TRAK2 | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs1337299999, COSV60275057; called by muse, varscan2
- TRAK2 | c.2695G>C p.A899P | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60275066; called by muse, mutect2, varscan2
- TRIOBP | c.2351A>G p.N784S | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs768806208, COSV60384353; called by muse, mutect2, varscan2
- UGT2B10 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 90/225 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV55323609; called by muse, mutect2, varscan2
- XIRP2 | c.5993G>T p.G1998V (on ENST00000628543; = p.G2173V on NM_152381.6) | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV54734096; called by muse, mutect2, varscan2
- ZNF676 | c.671C>A p.T224N (on ENST00000650058; = p.T192N on NM_001001411.3) | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV68094960; called by muse, mutect2, varscan2
- ZNF71 | c.1132G>T p.G378C | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100046345, COSV60150178; called by muse, mutect2, varscan2
- CCDC134 | c.499del p.Q167Rfs*34 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- DCN | c.282del p.E95Kfs*10 | Frame Shift Del (DEL) | VAF 53/147 reads (36%) | called by mutect2, pindel, varscan2
- FBN3 | c.6292G>A p.G2098S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2
- GABRA2 | c.45del p.F15Lfs*60 | Frame Shift Del (DEL) | VAF 107/315 reads (34%) | called by pindel, varscan2
- HMBS | c.999_1000del p.L334Gfs*24 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- IFT172 | c.1801A>C p.T601P | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- MAPKAPK2 | c.392_394del p.R131del | In Frame Del (DEL) | VAF 13/53 reads (25%) | called by pindel, varscan2
- ABCG8 | c.1095G>T p.T365= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV55396795, COSV55397031; called by muse, mutect2, varscan2
- ADAMTS9 | c.4029C>G p.T1343= | Silent (SNP) | VAF 31/55 reads (56%) | catalogued as COSV55790571; called by muse, mutect2, varscan2
- ANKRD17 | c.3489G>A p.Q1163= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV58227807; called by muse, varscan2
- CILP2 | c.2097C>T p.R699= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV52273021, COSV99364232; called by muse, varscan2
- DNAH10 | c.8869C>T p.L2957= (on ENST00000409039; = p.L2896= on NM_207437.3) | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs1342873412, COSV69001586; called by muse, mutect2, varscan2
- EEF1A2 | c.843G>T p.A281= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV53208311; called by muse, mutect2, varscan2
- FER1L5 | c.3528G>A p.V1176= (on ENST00000623019; = p.V1149= on NM_001293083.2) | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV67607069; called by muse, mutect2, varscan2
- GDNF | c.633C>T p.I211= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as CM005545, COSV58481906; called by muse, mutect2, varscan2
- GDPD2 | c.6C>T p.A2= | Silent (SNP) | VAF 35/37 reads (95%) | catalogued as rs762112029, COSV65534350; called by muse, mutect2, varscan2
- ICAM5 | c.345C>A p.R115= | Silent (SNP) | VAF 14/34 reads (41%) | called by muse, varscan2
- KCNH8 | c.2349C>T p.P783= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV60476750; called by muse, mutect2, varscan2
- MRPL21 | c.324G>C p.V108= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV62914063; called by muse, mutect2, varscan2
- MTREX | c.768T>C p.Y256= | Silent (SNP) | VAF 40/94 reads (43%) | catalogued as COSV57930183; called by muse, mutect2, varscan2
- MYO10 | c.3057A>G p.R1019= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV57029918; called by muse, mutect2, varscan2
- NOX4 | c.1575G>C p.R525= | Silent (SNP) | VAF 167/378 reads (44%) | catalogued as COSV54464837; called by muse, mutect2, varscan2
- NSD1 | c.60G>A p.V20= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV61784696; called by muse, mutect2, varscan2
- PCDH7 | c.2994T>A p.S998= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV62343531; called by muse, mutect2, varscan2
- PNPLA8 | c.1680T>A p.P560= | Silent (SNP) | VAF 47/129 reads (36%) | catalogued as COSV57554784; called by muse, mutect2, varscan2
- RSPH10B | c.2343A>G p.E781= | Silent (SNP) | VAF 112/376 reads (30%) | catalogued as COSV58075467; called by muse, mutect2, varscan2
- SALL3 | c.2136C>T p.C712= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs1233975579, COSV73306578; called by muse, mutect2, varscan2
- SLC25A52 | c.888C>T p.I296= (on ENST00000672005; = p.I286= on NM_001034172.4) | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as rs768083688, COSV52504423; called by muse, mutect2, varscan2
- SLC35B2 | c.705C>T p.Y235= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs538318523, COSV51491866; called by muse, mutect2, varscan2
- STON2 | c.2616T>G p.L872= (on ENST00000649389 / NM_001366849.2; = p.L815= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV50855109; called by muse, mutect2, varscan2
- TTN | c.30252T>C p.Y10084= (on ENST00000591111; = p.Y9157= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 77/172 reads (45%) | catalogued as COSV60128543; called by muse, mutect2, varscan2
- WASHC4 | c.3234G>A p.E1078= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV59892343; called by muse, mutect2, varscan2
- XIRP2 | c.2023T>C p.L675= (on ENST00000628543; = p.L850= on NM_152381.6) | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as COSV54734085; called by muse, mutect2, varscan2
- ZMYM2 | c.60G>A p.G20= | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as COSV67037604; called by muse, mutect2, varscan2
- ZNF43 | c.2055A>G p.K685= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV61685986; called by muse, mutect2, varscan2
- ZSCAN5A | c.522A>G p.P174= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs199886337, COSV54231838; called by muse, mutect2
- FARP1 | c.171+31231A>G | Intron (SNP) | VAF 30/55 reads (55%) | catalogued as rs1292717826, COSV60348064; called by muse, mutect2
- FUT9 | c.*5653C>A | 3'UTR (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100134471, COSV56148561, COSV56157988; called by muse, mutect2, varscan2
- LINC02872 | n.144G>T | RNA (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- MED13L | c.311-37096A>G | Intron (SNP) | VAF 54/79 reads (68%) | catalogued as COSV99930239; called by mutect2, varscan2
- PCDHAC1 | c.2433+205G>A | Intron (SNP) | VAF 30/80 reads (38%) | catalogued as COSV99169840; called by muse, mutect2, varscan2
- PPBPP1 | n.66G>T | RNA (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- SLC19A1 | c.*527T>C | 3'UTR (SNP) | VAF 4/23 reads (17%) | catalogued as rs1247828427; called by muse, varscan2
- ST3GAL5 | c.319-5001T>A | Intron (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
